Surgical pathology report (de-identified scan), TCGA case TCGA-UB-AA0V, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site UCSF, specimen TCGA-UB-AA0V-01A (Primary Tumor).

[page 1 of 6]
Results **Surgical Pathology Specimen Source (enter 1 per line): 1. left lobe of liver-permanent (long stitch marks lateral; smedium stitch marks medial) (Order**

Result Information

Status (Last updated Date/Time)

Edited

Accession #

CLF *ICD O-3* *NOS*
Carcinoma, hepatocellular
817013
Hyperplasia, focal nodular
Site Liver 0220

SURGICAL PATHOLOGY REPORT

* AMENDED *

Patient Name:

Med. Rec. #:

Sex:

Accession #:

Visit #:

Service Date:

Received:

Location:

Client:

Physician(s):

FINAL PATHOLOGIC DIAGNOSIS

Liver, left lobe, partial hepatectomy:

1. Focal nodular hyperplasia; see comment.
2. Minimal hemosiderosis; see comment.

COMMENT:

This report has been amended due to a typographical error in the diagnosis. The diagnosis and report remain otherwise unchanged.

Sections reveal a circumscribed, nodular proliferation of well-differentiated hepatocytes with associated thin, irregular fibrous bands demonstrating ductular reaction and aberrant arterioles, which focally abuts the hepatic capsule. The hepatocytes show intact trabecular architecture without cytologic atypia. Reticulin stain (performed on block A3) highlights hepatic plates of 1-2 cell thickness and shows no loss. The surgical margin is negative. In order to further characterize the lesion, immunohistochemical stains were performed on block A3, with the following results in the lesional hepatocytes:

- Glutamine synthetase: Positive in characteristic patchy, map-like staining pattern.
- SAA: Negative.

[page 2 of 6]
- CRP: Focal weak positive; predominantly negative.
- L-FABP: Positive (normal pattern).
- Beta-catenin: Membranous staining only (normal pattern).
- In addition, an immunostain for CD34 shows patchy sinusoidal endothelialization near fibrous septae.

The morphologic and immunohistochemical findings are those of excised focal nodular hyperplasia (FNH).

The non-lesional hepatic parenchyma shows few widely scattered portal tracts with minimal predominantly lymphocytic inflammation without interface activity. Bile ducts are intact without injury or loss. There is no significant lobular inflammation, and no necrotic hepatocytes are identified. Foci of glycogenated nuclei are seen. There is no steatosis or cholestasis. A trichrome stain (performed on block A5) overall shows no significant increased fibrosis; a few thin, periportal septae are identified, but these are focal and subcapsular in location. An iron stain (also performed on block A5), shows widely scattered small, patchy foci of 1-2+ staining, predominantly in hepatocytes and also in Kupffer cells (scale 0-4), some but not all of which show periportal distribution.

The findings in the background liver are minimal and non-specific. The pattern of minimal iron deposition is not entirely specific but may be compatible with genetic hemochromatosis in this context.

Selected slides of this case have also been reviewed by Dr. (A1, A3, and A4, including immunostains) and Dr. (slide A5, including iron and trichrome stains), who agree with the diagnosis.

Specimen(s) Received

A: Left lobe of liver-permanent (long stitch marks lateral; medium stitch marks medial) (FS)

Intraoperative Diagnosis

FS1 (A) Liver, left lobe, biopsy: Hepatocellular lesion, differential diagnosis includes focal nodular hyperplasia and variant adenoma. Dr. agrees. (Dr.

Clinical History

The patient is a year-old woman who, according to , has a known history of hemochromatosis (C282Y homozygous) and developed a 2 cm lesion in segment 2 of the liver, and had elevated alpha-fetoprotein. There is no cirrhosis on imaging studies.

Gross Description

The case is received in one part, fresh, labeled with the patient's name and medical record number, and additionally labeled "#1 left lobe liver," and consists of a portion of liver (55 gm; 7 cm from right to left x 2.8 cm from anterior to posterior x 10 cm from superior to inferior).

GROSS ABNORMALITIES: There is a firm, well-circumscribed, yellow-brown nodule (2.2 x 2 x 1.8 cm), located 1 cm from the parenchymal margin.

[page 3 of 6]
The nodule abuts the capsule and is 3.5 cm from the lateral edge. The vessels and ducts surrounding the nodule are patent. The surrounding parenchyma is uniformly pink-brown without other masses. No candidate lymph nodes are identified.

ORIENTED BY: Surgeon's sutures; short = medial; long = lateral.

INTRAOPERATIVE FINDINGS: Frozen section 1; nodule, subsequently submitted in cassette A1.

INKING:

- Liver capsule overlying mass: Blue.

- Parenchymal margin: Black.

POTENTIAL STUDIES: Fresh normal tissue and tumor are submitted to the Tissue Bank.

CASSETTES: Representative sections are submitted:

A1: Frozen section 1 remnant.

A2: Nodule and relationship to parenchymal margin.

A3-A4: Additional nodule.

A5: Normal-appearing parenchyma, 3 cm from nodule.

The immunohistochemical stains reported above were developed and their performance characteristics determined by the

They have not been cleared or approved by the U. S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high-complexity clinical testing.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides. The attending pathologist has reviewed all dictations, including prosector work, and preliminary interpretations performed by any resident involved in the case and performed all necessary edits before signing the final report.

Pathology PDF Report

Show images for Surgical Pathology Specimen Source (enter 1 per line): 1. left lobe of liver-permanent (long stitch marks lateral; smedium stitch marks medial)

Authorizing Provider Information

Name:

MD

Fax:

Phone:

Pager:

Signed by

Result History

SURGICAL PATHOLOGY (Order

Order Result History Report.

and Items

Surgical Pathology Specimen Source (enter 1 per line): 1. left lobe of liver-permanent (long stitch marks lateral; smedium stitch marks medial) (Order:

[page 4 of 6]
This is NOT a Requisition. Requisition hyperlink below.

Surgical Pathology Specimen Source (enter 1 per line): 1. left lobe of liver-permanent (long stitch marks lateral; smedium stitch marks medial)

(Order Pathology and Cytology Order:

Authorizing:

MD
Department:

Date:

Released By:

Show images for Surgical Pathology Specimen Source (enter 1 per line): 1. left lobe of liver-permanent (long stitch marks lateral; smedium stitch marks medial)

Order Information

Order Date/Time	Release Date/Time	Start Date/Time	End Date/Time
-----------------	-------------------	-----------------	---------------

Release Information

Released On	Released By
-------------	-------------

Order Details

Frequency	Duration	Priority	Order Class
Once	1 occurrence	Routine	Unit Collect

Order Questions

Question	Answer	Comment
COLLDATE		
COLLTIME		
ORPHONE		

Specimen Source (enter 1 per line)

1. left lobe of liver-permanent (long stitch marks lateral; smedium stitch marks medial) liver mass

Lab Collection and Receipt Information

Collect Date	Collect Time	Collected By	Lab Receipt Date	Lab Receipt Time
--------------	--------------	--------------	------------------	------------------

Collection Information

Resulting Agency

Order Provider Info

	Office phone	Pager/beeper	E-mail
Ordering User	--	--	--
Authorizing Provider	--	--	--

Electronically Signed By:

Electronically Authorized By

Electronically Ordered By

[page 5 of 6]
Acknowledgement Info

For At Acknowledged By Acknowledged On

Order Status for: SURGICAL PATHOLOGY

Parent Status: **Completed**

Child Orders

(This order does not yet have any children)

Order Requisition

Surgical Pathology Specimen Source (enter 1 per line): 1. left lobe of liver-permanent (long stitch marks lateral; smedium stitch marks medial) (Order

Per TSS, dx discrepancy from the frozen top section of the TC6A tumor was consistent w/ well-diff hepatocellular carcinoma.
BCP

[page 6 of 6]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on _____) Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Focal nodular hyperplasia	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Hepatocellular carcinoma	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	The frozen section top slide was consistent with a well-differentiated hepatocellular lesion, and immunostains (including beta-catenin and glutamine synthetase) and reticulin stain were required to differentiate between hepatocellular carcinoma, hepatic adenoma, and focal nodular hyperplasia (which ended up being the final pathologic diagnosis).	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file ef675744-bb2b-4443-94fc-4c38bfaad301 (TCGA-UB-AA0V.0BEA5A64-9DDE-45A8-A788-5EE2CEC6F6E4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).